Somatic mutation profile of tumor specimen PCProject_0161_T1_WES (aliquot PCProject_0161_T1_WES_1) from CMI case PCProject_0161, project CMI-MPC: Count Me In (CMI): The Metastatic Prostate Cancer (MPC) Project. Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Prostate gland; Age at diagnosis: 54.7 years (19,983 days).
Specimen PCProject_0161_T1_WES: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Solid Tissue; Biospecimen anatomic site: Lymph Node(s) Pelvic; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0d14e7f6-944b-4382-b7ac-4302c47a4c4d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen PCProject_0161_SALIVA (Saliva), aliquot PCProject_0161_SALIVA_1; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f9af13d8-9c2b-4f4f-b656-16a6b01704ea

The open-access MAF lists 46 somatic variants for this specimen: 31 protein-altering or splice-affecting, 10 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 24, Silent 10, Intron 5, Frame Shift Del 3, Nonsense Mutation 1, Frame Shift Ins 1, In Frame Del 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ANKRD17 | c.566C>T p.T189M | Missense Mutation (SNP) | VAF 24/89 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.883); catalogued as rs761404486; called by muse, mutect2, varscan2
- COL1A2 | c.2465G>A p.R822H | Missense Mutation (SNP) | VAF 83/542 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs1800240, COSV51955634; called by muse, mutect2, varscan2
- DIPK2B | c.1189C>T p.P397S | Missense Mutation (SNP) | VAF 171/226 reads (76%) | SIFT tolerated (0.47); PolyPhen benign (0.003); catalogued as rs750915161; called by muse, mutect2, varscan2
- DNM1 | c.176G>A p.R59Q | Missense Mutation (SNP) | VAF 38/388 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV57850688; called by muse, mutect2
- FOXM1 | c.1835C>T p.P612L | Missense Mutation (SNP) | VAF 12/61 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1312502969; called by muse, mutect2, varscan2
- FRAS1 | c.1883C>T p.P628L | Missense Mutation (SNP) | VAF 135/516 reads (26%) | SIFT tolerated (0.32); PolyPhen benign (0.001); catalogued as rs1477729784, COSV53604604; called by muse, mutect2, varscan2
- LAMA1 | c.3622G>A p.V1208I | Missense Mutation (SNP) | VAF 25/321 reads (8%) | SIFT tolerated (0.11); PolyPhen benign (0.045); catalogued as rs369286165; called by muse, mutect2
- MUC5B | c.4054G>A p.G1352S | Missense Mutation (SNP) | VAF 34/116 reads (29%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.531); catalogued as rs774607866, COSV101500287; called by muse, mutect2, varscan2
- MYO5A | c.4843C>T p.R1615W | Missense Mutation (SNP) | VAF 79/193 reads (41%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.757); catalogued as rs1432810247; called by muse, mutect2, varscan2
- PRR23A | c.779G>A p.R260H | Missense Mutation (SNP) | VAF 8/35 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.04); catalogued as COSV67214028; called by muse, mutect2
- RIOK3 | c.409A>G p.T137A | Missense Mutation (SNP) | VAF 26/158 reads (16%) | SIFT tolerated (0.8); PolyPhen benign (0.135); catalogued as rs1230223993; called by muse, mutect2, varscan2
- YTHDF1 | c.1087G>A p.E363K | Missense Mutation (SNP) | VAF 37/125 reads (30%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.707); catalogued as rs1441706015, COSV100945595; called by muse, mutect2, varscan2
- ABCC12 | c.2115G>T p.L705F | Missense Mutation (SNP) | VAF 18/135 reads (13%) | SIFT tolerated (0.57); PolyPhen benign (0.411); called by mutect2, varscan2
- ANKRD12 | c.3052G>C p.D1018H | Missense Mutation (SNP) | VAF 14/117 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ARMCX5 | c.904T>A p.S302T | Missense Mutation (SNP) | VAF 58/93 reads (62%) | SIFT tolerated (0.16); PolyPhen benign (0.063); called by muse, mutect2, varscan2
- CACNA1B | c.4770del p.W1590* | Frame Shift Del (DEL) | VAF 76/196 reads (39%) | called by mutect2, pindel, varscan2
- EID3 | c.92C>A p.T31N | Missense Mutation (SNP) | VAF 52/258 reads (20%) | SIFT tolerated (0.43); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- GFM2 | c.745_747del p.N249del | In Frame Del (DEL) | VAF 21/134 reads (16%) | called by mutect2, pindel, varscan2
- KMT2B | c.8045G>A p.R2682H | Missense Mutation (SNP) | VAF 36/287 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- MCF2L2 | c.3172_3173del p.R1058Gfs*13 | Frame Shift Del (DEL) | VAF 15/77 reads (19%) | called by pindel, varscan2
- MTTP | c.264dup p.V89Cfs*2 | Frame Shift Ins (INS) | VAF 32/152 reads (21%) | called by mutect2, pindel, varscan2
- MUC12 | c.5336A>T p.H1779L (on ENST00000379442; = p.H1636L on NM_001164462.1) | Missense Mutation (SNP) | VAF 108/313 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.234); called by muse, mutect2, varscan2
- NRIP1 | c.1813del p.S605Afs*30 | Frame Shift Del (DEL) | VAF 13/85 reads (15%) | called by mutect2, pindel, varscan2
- NRL | c.215T>C p.L72P | Missense Mutation (SNP) | VAF 85/315 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- P4HB | c.1021G>A p.E341K | Missense Mutation (SNP) | VAF 49/301 reads (16%) | SIFT tolerated (0.46); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- PLEKHH2 | c.3247T>C p.Y1083H | Missense Mutation (SNP) | VAF 21/68 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PMS2 | c.537+8A>T | Splice Region (SNP) | VAF 21/155 reads (14%) | called by muse, mutect2, varscan2
- PTPRC | c.2362A>T p.R788* | Nonsense Mutation (SNP) | VAF 104/561 reads (19%) | called by muse, mutect2, varscan2
- SLC44A4 | c.622C>G p.L208V | Missense Mutation (SNP) | VAF 37/163 reads (23%) | SIFT tolerated (0.19); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- TDRD3 | c.698G>C p.S233T | Missense Mutation (SNP) | VAF 45/168 reads (27%) | SIFT tolerated (0.16); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- ZCCHC3 | c.43C>T p.R15W | Missense Mutation (SNP) | VAF 3/49 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.011); called by muse, mutect2
- ADAMTS12 | c.4173C>T p.C1391= | Silent (SNP) | VAF 17/156 reads (11%) | catalogued as rs532835414, COSV61267744; called by muse, mutect2, varscan2
- FNTA | c.12C>A p.T4= | Silent (SNP) | VAF 6/54 reads (11%) | called by muse, mutect2
- GRM3 | c.870C>T p.R290= | Silent (SNP) | VAF 34/161 reads (21%) | catalogued as rs750137951, COSV64470967; called by muse, mutect2, varscan2
- HOXD13 | c.219C>T p.G73= | Silent (SNP) | VAF 26/84 reads (31%) | called by muse, mutect2, varscan2
- MPO | c.1182G>A p.A394= | Silent (SNP) | VAF 22/252 reads (9%) | catalogued as rs1336983792, COSV56563505; called by muse, mutect2
- POTEC | c.708T>C p.D236= | Silent (SNP) | VAF 11/211 reads (5%) | called by muse, mutect2
- TOPBP1 | c.723C>T p.L241= | Silent (SNP) | VAF 26/73 reads (36%) | catalogued as rs375922864; called by muse, mutect2
- USH2A | c.7428C>T p.G2476= | Silent (SNP) | VAF 215/494 reads (44%) | catalogued as rs150372183; called by muse, mutect2, varscan2
- WNT1 | c.366A>C p.R122= | Silent (SNP) | VAF 59/214 reads (28%) | called by muse, mutect2, varscan2
- ZFHX4 | c.4830C>T p.I1610= | Silent (SNP) | VAF 22/260 reads (8%) | called by muse, mutect2
- CHCHD5 | c.309+18C>A | Intron (SNP) | VAF 76/307 reads (25%) | catalogued as COSV100260959; called by muse, mutect2, varscan2
- RBFOX1 | c.1071+415C>A | Intron (SNP) | VAF 20/256 reads (8%) | called by muse, mutect2
- ZCCHC10 | c.107+3724G>A | Intron (SNP) | VAF 52/162 reads (32%) | called by muse, mutect2, varscan2
- ZDHHC3 | c.610+163G>A | Intron (SNP) | VAF 36/261 reads (14%) | catalogued as rs763427201; called by muse, mutect2, varscan2
- ZNF497 | c.-111-841C>T | Intron (SNP) | VAF 32/82 reads (39%) | catalogued as rs763516353; called by muse, mutect2, varscan2
